MMRF case MMRF_1178 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/aa308f50-2dd1-4327-a88c-cde8b35cd67b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.8 years (22,222 days); ISS stage: III; Days to last known disease status: 1,593 days (4.4 years); Days to last follow up: 1,593 days (4.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 150 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 130 days; Days to treatment end: 162 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 163 days; Days to treatment end: 163 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -41 (ECOG 0): M Protein 3.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Immunoglobulin G 2.19 g/L; Immunoglobulin A 65.4 g/L; Immunoglobulin M 0.02 g/L; Beta 2 Microglobulin 8.56 µg/mL; Lactate Dehydrogenase 1.37 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 3.75 ×10⁹/L; Absolute Neutrophil 1.69 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 30 g/L; Total Protein 9.9 g/dL; Glucose 4.29 mmol/L.
- Day 39 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Immunoglobulin G 3.01 g/L; Immunoglobulin A 10.3 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.93 µg/mL; Hemoglobin 8.49 mmol/L; Leukocytes 5.86 ×10⁹/L; Absolute Neutrophil 3.37 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 3.96 mmol/L.
- Day 182 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 4.16 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.37 µg/mL; Hemoglobin 7.94 mmol/L; Leukocytes 8.04 ×10⁹/L; Absolute Neutrophil 5.18 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 5.45 mmol/L.
- Day 227 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.312 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 3.15 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.01 µg/mL; Hemoglobin 8.99 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 47 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.
- Day 315: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.367 mg/dL; Immunoglobulin G 4.65 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.91 µg/mL; Hemoglobin 9.55 mmol/L; Leukocytes 5.33 ×10⁹/L; Absolute Neutrophil 3.03 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.55 mmol/L; Albumin 48 g/L; Total Protein 6.6 g/dL; Glucose 4.84 mmol/L.
- Day 429: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.407 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 5.51 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 9.61 mmol/L; Leukocytes 6.14 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.5 mmol/L; Albumin 48 g/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 497: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 5.49 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 3.17 µg/mL; Hemoglobin 9.36 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 8.25 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 6.66 mmol/L.
- Day 527: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.452 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.379 mg/dL; Immunoglobulin G 5.88 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.96 µg/mL; Hemoglobin 9.61 mmol/L; Leukocytes 6.02 ×10⁹/L; Absolute Neutrophil 2.75 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 46 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.
- Day 646: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 6.24 g/L; Immunoglobulin A 0.92 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.86 µg/mL; Hemoglobin 9.98 mmol/L; Leukocytes 6.15 ×10⁹/L; Absolute Neutrophil 3.59 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.53 mmol/L; Albumin 49 g/L; Total Protein 6.8 g/dL; Glucose 5.45 mmol/L.
- Day 742: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 6.41 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 1.86 µg/mL; Hemoglobin 9.67 mmol/L; Leukocytes 5.21 ×10⁹/L; Absolute Neutrophil 2.34 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.53 mmol/L; Albumin 47 g/L; Total Protein 6.8 g/dL; Glucose 4.9 mmol/L.
- Day 833: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 6.12 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 9.61 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.5 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 4.18 mmol/L.
- Day 924: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 6.41 g/L; Immunoglobulin A 1.55 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 2.48 µg/mL; Hemoglobin 9.49 mmol/L; Leukocytes 8.28 ×10⁹/L; Absolute Neutrophil 5.01 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.53 mmol/L; Albumin 47 g/L; Total Protein 7 g/dL; Glucose 5.39 mmol/L.
- Day 1,019: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.19 mg/dL; Immunoglobulin G 5.67 g/L; Immunoglobulin A 4.3 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2 µg/mL; Hemoglobin 10.2 mmol/L; Leukocytes 5.21 ×10⁹/L; Absolute Neutrophil 2.02 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.55 mmol/L; Albumin 48 g/L; Total Protein 7 g/dL; Glucose 4.46 mmol/L.
- Day 1,114: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14 mg/dL; Immunoglobulin G 4.12 g/L; Immunoglobulin A 9.69 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 2.2 µg/mL; Hemoglobin 9.73 mmol/L; Leukocytes 4.48 ×10⁹/L; Absolute Neutrophil 1.75 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.
- Day 1,214: M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17.9 mg/dL; Immunoglobulin G 3.44 g/L; Immunoglobulin A 13.1 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.74 µg/mL; Hemoglobin 9.8 mmol/L; Leukocytes 8.76 ×10⁹/L; Absolute Neutrophil 6.02 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 5.45 mmol/L.
- Day 1,304: M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.6 mg/dL; Immunoglobulin G 3.08 g/L; Immunoglobulin A 12.9 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.59 µg/mL; Hemoglobin 9.73 mmol/L; Leukocytes 4.73 ×10⁹/L; Absolute Neutrophil 2.19 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.89 mmol/L.
- Day 1,410 (ECOG 0): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.9 mg/dL; Immunoglobulin G 3.08 g/L; Immunoglobulin A 16 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.7 µg/mL; Hemoglobin 9.24 mmol/L; Leukocytes 6.64 ×10⁹/L; Absolute Neutrophil 3.67 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.63 mmol/L; Albumin 40 g/L; Total Protein 7.9 g/dL; Glucose 5.23 mmol/L.
- Day 1,498: M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 20.4 mg/dL; Immunoglobulin G 2.75 g/L; Immunoglobulin A 19.7 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 3.29 µg/mL; Hemoglobin 8.8 mmol/L; Leukocytes 5.64 ×10⁹/L; Absolute Neutrophil 3.18 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 6.6 mmol/L.
- Day 1,593 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.641 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 20.1 mg/dL; Immunoglobulin G 2.53 g/L; Immunoglobulin A 23.5 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 4.03 µg/mL; Hemoglobin 8.68 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.6 mmol/L; Albumin 40 g/L; Total Protein 7.9 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day -41: Weight: 88 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1178_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -41 days.
- Sample MMRF_1178_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -41 days.
